Gene-level copy-number profile of tumor specimen TCGA-24-1552-01A from TCGA case TCGA-24-1552, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.0 years (28,129 days).
Specimen TCGA-24-1552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ba336da3-a3ac-4707-a55b-71fa7068a4e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1552-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1519b6e7-6670-4d08-917e-f96cad5d8b46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,503; copy number 2: 24,111; copy number 3: 22,800; copy number 4: 4,883; copy number 5: 2,574; copy number 6: 156; copy number 7: 124; copy number 8: 199; copy number 9: 64; copy number 10: 200; copy number 11: 92; copy number 15: 11; copy number 21: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1552-01A-01D-0497-01): tumor purity 0.91, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,506 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–146,036,746, 100 genes, copy number 8 (broad region; genes not listed).
- chr1:148,246,169–149,048,286, 33 genes, copy number 7 (within-gene range 3–7): AC239809.2, RNVU1-22, LINC01731, AC245100.3, LINC01138, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2, AC245100.8, AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1.
- chr2:38,814–48,776,517, 827 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:104,502,700–115,721,490, 168 genes, copy number 8–15 (broad region; genes not listed).
- chr3:115,837,870–115,838,159, 1 gene, copy number 8: RN7SL815P.
- chr7:17,405,479–20,314,512, 30 genes, copy number 5 (within-gene range 3–5): AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1.
- chr8:41,577,187–42,139,752, 15 genes, copy number 9: GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4.
- chr8:42,338,454–43,363,518, 36 genes, copy number 8 (within-gene range 3–8): POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–6 (broad region; genes not listed).
- chr9:67,832,765–70,414,624, 44 genes, copy number 5: ANKRD20A1, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9.
- chr9:70,579,163–70,579,461, 1 gene, copy number 5: RN7SL726P.
- chr9:75,401,889–78,031,811, 28 genes, copy number 5: AL158073.1, AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9, GCNT1, H3P32, PPIAP87, PRUNE2, PCA3, AL359314.1, AL390239.1, AL353637.2, DNAJB5P1, LYPLA2P3, AL353637.1, FOXB2, ATP5MFP3, RFC5P1, VPS13A-AS1, VPS13A, GNA14, GNA14-AS1, NUTF2P3, RNU6-1303P, GNAQ.
- chr9:79,036,413–79,915,736, 10 genes, copy number 5: KRT18P24, AL512634.1, CHCHD2P9, LNCARSR, TLE4, AL161912.3, NPAP1P6, AL161912.1, AL161912.2, AL161912.4.
- chr12:66,767–3,371,346, 86 genes, copy number 5 (broad region; genes not listed).
- chr15:71,818,396–72,738,475, 36 genes, copy number 5: AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4.
- chr19:4,903,080–7,383,385, 95 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:27,638,483–40,090,925, 462 genes, copy number 5–21 (within-gene range 2–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
